Somatic mutation profile of tumor specimen TCGA-B8-4153-01B (aliquot TCGA-B8-4153-01B-11D-1669-08) from TCGA case TCGA-B8-4153, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 74.0 years (27,031 days).
Specimen TCGA-B8-4153-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27eedac2-9a0e-4ad5-a005-383287a22316.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4153-11A (Solid Tissue Normal), aliquot TCGA-B8-4153-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c6c1dbe-72c7-4dc7-9b60-0cec33769311

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Frame Shift Del 4, Nonsense Mutation 3, Intron 1, Translation Start Site 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKNAD1 | c.1846A>T p.N616Y | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV62204570; called by muse, mutect2, varscan2
- ALDH16A1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV53197342, COSV99513237; called by muse, mutect2, varscan2
- ALDH1A1 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV52794969; called by muse, mutect2, varscan2
- ARID1B | c.4071G>C p.P1357= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as CS121898, COSV51683873; called by muse, mutect2, varscan2
- ASAP1 | c.2839G>C p.A947P | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63055266; called by muse, mutect2, varscan2
- AXL | c.2294G>A p.G765E (on ENST00000301178 / NM_021913.5; = p.G756E on NM_001699.6) | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs868015563, COSV56576045; called by muse, mutect2, varscan2
- BICD1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV55689562; called by muse, mutect2, varscan2
- CA5B | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.213); catalogued as COSV59418019; called by muse, mutect2
- CEP135 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV57263313; called by muse, mutect2, varscan2
- CHD4 | c.512A>C p.D171A | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58912459; called by muse, mutect2
- CLEC4M | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV50217221; called by muse, mutect2, varscan2
- CMA1 | c.260C>G p.T87R | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51626593; called by muse, mutect2, varscan2
- CYP2A13 | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781487437, COSV57840487; called by muse, mutect2, varscan2
- DNAJC3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as COSV65133375; called by muse, mutect2, varscan2
- ETFB | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs145173884; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD6 | c.2593G>T p.D865Y | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV59697758; called by muse, mutect2, varscan2
- GALNT6 | c.1601A>G p.Q534R | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62543566; called by muse, mutect2, varscan2
- LAMC1 | c.3776G>A p.R1259K | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51186091; called by muse, mutect2, varscan2
- LPA | c.5069T>C p.L1690P | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60314369; called by muse, mutect2, varscan2
- MAN2C1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs766524476, COSV51242266; called by muse, mutect2, varscan2
- MAP3K10 | c.416C>A p.A139E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV53421485, COSV53425720; called by muse, mutect2, varscan2
- MBNL1 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770696564, COSV56836746; called by muse, mutect2
- MC3R | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV54765231; called by muse, mutect2, varscan2
- MC4R | c.255C>A p.S85R | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55353498; called by muse, mutect2, varscan2
- MTAP | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 38/435 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV66478691; called by muse, mutect2
- MTMR11 | c.1249C>G p.P417A (on ENST00000439741 / NM_001145862.2; = p.P345A on NM_181873.3) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV54967205, COSV99640853; called by muse, mutect2, varscan2
- MUC5B | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs377460516; called by muse, mutect2
- NF2 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV58532177; called by muse, mutect2, varscan2
- OMD | c.641T>A p.L214Q | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65020565; called by muse, mutect2, varscan2
- OTOL1 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV60008716; called by muse, mutect2
- PDCD11 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV63935644; called by muse, mutect2, varscan2
- PHGDH | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV65584939; called by muse, mutect2, varscan2
- PRB2 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 171/656 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV66984458; called by muse, mutect2, varscan2
- PTCH1 | c.3023G>A p.S1008N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.071); catalogued as COSV59497232; called by muse, mutect2, varscan2
- PTPRB | c.1242T>G p.N414K | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV54256330; called by muse, mutect2, varscan2
- RPS27 | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV55159364; called by muse, mutect2
- RTTN | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 66/193 reads (34%) | catalogued as rs200495808, COSV55353642; called by muse, mutect2, varscan2
- SAMD8 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65511491; called by muse, mutect2, varscan2
- SGPP2 | c.549C>G p.D183E | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1416373263, COSV58332358; called by muse, mutect2
- SLC9A1 | c.565A>C p.I189L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV56057502; called by muse, mutect2, varscan2
- TET2 | c.1346T>A p.V449E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV54436169; called by muse, mutect2, varscan2
- TREM2 | c.538del p.A180Pfs*9 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as COSV100632633, COSV58293842, COSV58295576; called by mutect2, pindel, varscan2
- UNC5CL | c.235T>A p.F79I | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV55112436; called by muse, mutect2, varscan2
- VPS37A | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV61366245; called by muse, mutect2, varscan2
- WDR62 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269700889, COSV54340330; called by muse, mutect2, varscan2
- ZNF121 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as COSV57551211, COSV57552634; called by muse, mutect2
- ADAMTS5 | c.438del p.F146Lfs*20 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- AKAP8L | c.1028del p.G343Afs*10 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | called by mutect2, pindel, varscan2
- HERC4 | c.405_407del p.D136del | In Frame Del (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- MERTK | c.1997dup p.P667Afs*68 | Frame Shift Ins (INS) | VAF 79/240 reads (33%) | called by mutect2, pindel, varscan2
- TSEN34 | c.280_282dup p.F94dup | In Frame Ins (INS) | VAF 33/114 reads (29%) | called by mutect2, pindel, varscan2
- ZNF148 | c.1917del p.Q640Sfs*7 | Frame Shift Del (DEL) | VAF 83/274 reads (30%) | called by mutect2, pindel, varscan2
- ABCC10 | c.1491G>A p.R497= (on ENST00000372530 / NM_001198934.2; = p.R454= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/192 reads (36%) | catalogued as COSV55094829; called by muse, mutect2, varscan2
- ASAP1 | c.2838G>C p.L946= | Silent (SNP) | VAF 49/212 reads (23%) | catalogued as COSV63048737, COSV63055273; called by muse, mutect2, varscan2
- CBFA2T3 | c.609G>A p.V203= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV51923349; called by muse, mutect2, varscan2
- CHD9 | c.5154T>G p.V1718= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV54617615; called by muse, mutect2, varscan2
- DCSTAMP | c.951G>C p.L317= | Silent (SNP) | VAF 24/482 reads (5%) | catalogued as COSV52580587; called by muse, mutect2
- GBA | c.837G>A p.L279= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV59171311; called by muse, mutect2
- GRM4 | c.330C>A p.S110= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV65220726; called by muse, mutect2, varscan2
- IGHA2 | c.183G>A p.G61= | Silent (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- LAMA5 | c.4053G>C p.L1351= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV53374390; called by muse, mutect2, varscan2
- MAP3K3 | c.640C>T p.L214= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV62282062; called by muse, mutect2, varscan2
- ORMDL2 | c.294C>T p.S98= | Silent (SNP) | VAF 72/245 reads (29%) | catalogued as COSV54479495; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.702G>A p.L234= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV57969815; called by muse, mutect2, varscan2
- RPS18 | c.69G>A p.R23= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as COSV71403655; called by muse, mutect2, varscan2
- SALL1 | c.3675A>G p.S1225= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV51765385; called by muse, mutect2, varscan2
- SCFD1 | c.837A>T p.A279= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV61728161; called by muse, mutect2, varscan2
- SLC39A1 | c.306C>A p.A102= | Silent (SNP) | VAF 111/343 reads (32%) | catalogued as COSV57846100; called by muse, mutect2, varscan2
- SLITRK1 | c.1371C>T p.N457= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as rs1032347594, COSV65675285; called by muse, mutect2
- USP7 | c.1959T>C p.D653= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as rs761788371, COSV61217984; called by muse, mutect2
- MACF1 | c.15832-10619C>T | Intron (SNP) | VAF 32/77 reads (42%) | catalogued as COSV57148666; called by muse, mutect2, varscan2
